Somatic mutation profile of tumor specimen ALCH-B3KK-TTP1-A (aliquot ALCH-B3KK-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3KK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.5 years (27,207 days).
Specimen ALCH-B3KK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab97e49f-80e2-48bd-a0b9-21db63b685dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3KK-NB1-A (Blood Derived Normal), aliquot ALCH-B3KK-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a555d726-2bb4-44a4-b589-885eff3e8d65

The open-access MAF lists 219 somatic variants for this specimen: 149 protein-altering or splice-affecting, 50 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 50, Nonsense Mutation 11, Intron 9, RNA 4, Splice Region 3, 3'UTR 3, 5'UTR 2, 5'Flank 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RET | c.2370G>T p.L790F | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs75030001, CM981705, CM981706; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 39/197 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as rs1488048019; called by muse, mutect2, varscan2
- ALMS1 | c.9599C>T p.A3200V | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286644755; called by muse, mutect2
- ARFGEF3 | c.2648G>T p.R883L | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as COSV52450223; called by muse, mutect2
- AXIN1 | c.1493A>G p.H498R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.46); catalogued as COSV51987592; called by muse, mutect2, varscan2
- CPED1 | c.2425G>A p.V809I | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs891170447, COSV60009824; called by muse, mutect2
- CYP2B6 | c.790C>A p.L264I | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs968750756; called by muse, mutect2, varscan2
- CYP2C18 | c.291A>T p.R97S | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53671392; called by muse, mutect2
- DIP2C | c.478A>G p.M160V | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1376592795; called by muse, mutect2
- DLC1 | c.1637G>A p.R546K (on ENST00000276297 / NM_001348081.2; = p.R109K on NM_006094.5) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs1382061083, COSV52294963; called by muse, mutect2
- DNAH8 | c.5726C>G p.S1909* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV59487065; called by muse, mutect2
- FAM47C | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.08); catalogued as COSV63726751; called by muse, mutect2, varscan2
- FAT1 | c.11453G>T p.C3818F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV101499226, COSV71674852; called by muse, mutect2, varscan2
- FLRT1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755446395; called by muse, mutect2, varscan2
- GATA3 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV60517710; called by muse, mutect2
- HEXA | c.1337C>G p.P446R | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs939203533, CD972254; ClinVar: uncertain significance; called by muse, mutect2
- IMPG1 | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV64058829; called by muse, mutect2, varscan2
- KCNQ3 | c.1044G>A p.A348= | Splice Region (SNP) | VAF 44/320 reads (14%) | catalogued as rs541549782, COSV101196037; ClinVar: likely benign; called by muse, mutect2, varscan2
- KNTC1 | c.5261C>A p.A1754D | Missense Mutation (SNP) | VAF 29/333 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV61085145; called by muse, mutect2
- NAGA | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67170056; called by muse, mutect2
- NPC1L1 | c.3488G>T p.R1163L | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.185); catalogued as COSV56923615; called by muse, mutect2
- NR2C2AP | c.13T>G p.L5V | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs1240954082; called by muse, mutect2
- OR6F1 | c.551G>T p.W184L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.657); catalogued as COSV100129524; called by muse, mutect2
- OR6K2 | c.566C>G p.T189R | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs148403435; called by muse, mutect2, varscan2
- PCDHB5 | c.1450C>A p.Q484K | Missense Mutation (SNP) | VAF 36/510 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.755); catalogued as rs1331009398; called by muse, mutect2
- PDE11A | c.2224G>A p.V742M | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761760055, COSV53698945; called by muse, mutect2
- PDGFRB | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55801446; called by muse, mutect2
- PKD2 | c.2679G>T p.R893S | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV99417541; called by muse, mutect2
- PLCB4 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99596444; called by muse, mutect2, varscan2
- POTEF | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV62540919; called by mutect2, varscan2
- RIMS1 | c.4191G>C p.K1397N | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs372513852; called by muse, mutect2
- SCGN | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58544992; called by muse, mutect2, varscan2
- SLC5A5 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV55834227; called by muse, mutect2
- SLC5A5 | c.1842C>G p.F614L | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs752445428, COSV55831920; called by muse, mutect2
- SLC9A9 | c.872C>A p.A291E | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as rs142411857, COSV57235665; called by muse, mutect2, varscan2
- SLCO1C1 | c.1490C>A p.T497K | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99859653; called by muse, mutect2
- SRCAP | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52676044; called by muse, mutect2
- ST18 | c.2108C>A p.A703D | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV99388649; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 12/122 reads (10%) | PolyPhen probably damaging (0.981); catalogued as COSV60321262; called by muse, mutect2
- TFPI2 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.054); catalogued as COSV55991183; called by muse, mutect2
- TLR4 | c.1606G>T p.D536Y (on ENST00000355622 / NM_138554.5; = p.D496Y on NM_003266.4) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62923009; called by muse, mutect2
- TMEM132D | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.943); catalogued as rs749019418, COSV70601176; called by muse, mutect2
- TNXB | c.7625C>A p.P2542H (on ENST00000647633; = p.P2295H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV100926553; called by muse, mutect2, varscan2
- TRPM8 | c.2167C>A p.L723M | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.201); catalogued as rs1357531821; called by muse, mutect2
- WDFY1 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1010327999; called by muse, mutect2, varscan2
- ZBED6 | c.2293A>G p.I765V | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs903495251; called by muse, mutect2
- ZNF354B | c.1750G>T p.G584W | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59365915; called by muse, mutect2
- ACTN2 | c.1346G>A p.S449N | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2
- ADGRB3 | c.4177G>T p.D1393Y | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2
- AGT | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 37/436 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANGPTL6 | c.224T>A p.L75Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AOX1 | c.1086G>T p.R362S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.149); called by muse, mutect2
- AP2A2 | c.1411C>G p.R471G | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2
- AP5Z1 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2
- ASPM | c.8109G>T p.R2703S | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.388); called by muse, mutect2
- ATP6AP2 | c.981T>G p.I327M (on ENST00000378438; = p.I328M on NM_005765.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BHMG1 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.024); called by muse, mutect2
- BLM | c.3143del p.N1048Mfs*30 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel, varscan2
- BRD4 | c.2185G>T p.G729W | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C6 | c.964G>T p.V322F | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNG7 | c.644C>A p.A215D | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.118); called by muse, mutect2
- CCNT1 | c.35G>T p.W12L | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD109 | c.1858G>T p.G620* | Nonsense Mutation (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- CELF4 | c.1249+2T>C p.X417_splice | Splice Site (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- CFAP65 | c.1697C>A p.T566N | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- CHRM2 | c.309C>G p.D103E | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CNOT4 | c.974C>T p.P325L (on ENST00000315544 / NM_001190848.1; = p.P322L on NM_013316.4) | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- CNTNAP4 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- COQ9 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2
- CPN2 | c.364T>A p.S122T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.272); called by muse, mutect2
- CPS1 | c.2661G>C p.M887I | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- CTNND2 | c.1196A>T p.Y399F | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DNAH5 | c.2526G>T p.Q842H | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- DYM | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- DYNC1H1 | c.8121G>T p.Q2707H | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPS15 | c.1158A>T p.K386N | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- ERMARD | c.996G>T p.L332F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2
- FAT4 | c.7155G>T p.L2385F | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- FLNC | c.6917T>G p.V2306G | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FRG2C | c.646G>C p.G216R | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIMAP7 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- GOLGA8S | c.1110G>T p.L370= | Splice Region (SNP) | VAF 10/322 reads (3%) | called by muse, mutect2
- GRM8 | c.1679A>T p.Q560L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2
- GRPR | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H3-5 | c.235A>T p.N79Y | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.279); called by muse, mutect2
- IGKC | c.285C>G p.S95R | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- KCNJ4 | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); called by muse, varscan2
- KNDC1 | c.2557G>T p.G853W | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- KRT7 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2
- LAMA2 | c.2112C>A p.N704K | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- LBP | c.1198G>C p.G400R | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LBP | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LGI1 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP8 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- MAEL | c.200A>T p.K67M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.373); called by muse, mutect2
- MCM9 | c.1386G>T p.Q462H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MCPH1 | c.2393G>T p.G798V | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.3828G>T p.Q1276H | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- MT1A | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYBPC2 | c.2167C>A p.Q723K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2
- MYH8 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- NBEAL1 | c.5655A>T p.K1885N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NLGN1 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- NRP1 | c.2000A>G p.N667S | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NUB1 | c.1421A>C p.Q474P | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.113); called by muse, mutect2
- OR10J1 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- OR1S1 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T33 | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 18/401 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.26); called by muse, mutect2
- OR4D2 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 14/335 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- OR4N5 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4Q2 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- OR52N5 | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR56B4 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- PADI6 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 11/223 reads (5%) | called by muse, mutect2
- PCDHA1 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- PCDHGA3 | c.2315A>T p.Q772L | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PHACTR2 | c.834C>G p.H278Q | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- PNISR | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2
- POLR3B | c.1504A>T p.I502F | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PPP4R1 | c.946G>T p.G316* (on ENST00000400556 / NM_001042388.3; = p.G299* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2, varscan2
- PSG6 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2
- RTN4RL2 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 14/195 reads (7%) | called by muse, mutect2
- SCLT1 | c.1658C>A p.S553* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- SCUBE3 | c.753C>A p.C251* | Nonsense Mutation (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2
- SEMA3G | c.2302G>T p.V768L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, mutect2
- SH3GL2 | c.135G>T p.R45S | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- SHCBP1 | c.1252G>T p.G418C | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC12A1 | c.2633G>C p.G878A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- SLC12A3 | c.1639T>A p.C547S | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLIT2 | c.4315A>G p.S1439G | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2
- SPAG1 | c.1601T>C p.L534P | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SPATA31A7 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- STAB2 | c.3757A>T p.T1253S | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2
- SV2B | c.170_176del p.D57Afs*22 | Frame Shift Del (DEL) | VAF 20/214 reads (9%) | called by mutect2, pindel
- TEX14 | c.1396A>G p.K466E (on ENST00000240361 / NM_001201457.2; = p.K460E on NM_031272.5) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THBD | c.1196A>T p.H399L | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIMD4 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- TRIM49C | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.049); called by muse, mutect2
- TRPA1 | c.683G>C p.R228T | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.301); called by muse, mutect2
- TRPA1 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2
- TRPM4 | c.1874-7G>C | Splice Region (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- TTN | c.40790C>A p.A13597D (on ENST00000591111; = p.A6173D on NM_003319.4) | Missense Mutation (SNP) | VAF 15/186 reads (8%) | PolyPhen possibly damaging (0.564); called by muse, mutect2
- UBR2 | c.2786G>C p.G929A | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- UPK1A | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 28/329 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UPK1A | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 28/331 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VGLL2 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2
- WDR81 | c.4382C>G p.S1461C (on ENST00000409644 / NM_001163809.2; = p.S410C on NM_152348.4) | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF512B | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2
- ACP4 | c.348C>A p.A116= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- ALPK1 | c.1860G>A p.Q620= | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- ARFGEF1 | c.2373A>C p.P791= | Silent (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- ARHGEF5 | c.996G>T p.V332= | Silent (SNP) | VAF 24/548 reads (4%) | called by muse, mutect2
- ASTL | c.1227C>A p.V409= | Silent (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- ATP13A4 | c.1323G>T p.A441= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- B3GNT2 | c.312G>T p.S104= | Silent (SNP) | VAF 27/264 reads (10%) | called by muse, mutect2, varscan2
- BHMG1 | c.93A>T p.L31= | Silent (SNP) | VAF 21/218 reads (10%) | called by muse, mutect2
- C4orf54 | c.1785G>T p.G595= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- CDH10 | c.774G>C p.T258= | Silent (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2
- CDK2AP1 | c.330A>G p.E110= | Silent (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- CEP192 | c.948T>C p.D316= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs1025859814; called by muse, mutect2, varscan2
- COL20A1 | c.2331C>T p.P777= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs148669802, COSV58918609; called by mutect2, varscan2
- DCC | c.3444C>A p.L1148= | Silent (SNP) | VAF 19/317 reads (6%) | called by muse, mutect2
- GATA5 | c.906C>A p.G302= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- HDAC9 | c.2133G>A p.K711= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- HTR3E | c.636T>C p.H212= (on ENST00000415389 / NM_001256613.1; = p.H227= on NM_182589.2) | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs1244710562; called by muse, mutect2, varscan2
- INSR | c.1050G>T p.S350= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as COSV100253243; called by muse, mutect2
- INSRR | c.1065C>A p.I355= | Silent (SNP) | VAF 10/223 reads (4%) | called by muse, mutect2
- IRX1 | c.516G>C p.T172= | Silent (SNP) | VAF 31/296 reads (10%) | catalogued as COSV100116760; called by muse, mutect2, varscan2
- JCAD | c.663G>A p.L221= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs975095622; called by muse, mutect2
- LANCL1 | c.924G>T p.V308= | Silent (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2, varscan2
- LMAN1 | c.723A>G p.Q241= | Silent (SNP) | VAF 37/303 reads (12%) | catalogued as rs1568116813; called by muse, mutect2, varscan2
- LRP1B | c.6492C>A p.S2164= | Silent (SNP) | VAF 18/220 reads (8%) | catalogued as COSV101256323; called by muse, mutect2
- LRRK2 | c.7260G>A p.Q2420= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV54148821; called by muse, mutect2
- MAB21L1 | c.210C>T p.S70= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- NEBL | c.1209C>T p.I403= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- NOVA1 | c.366A>G p.E122= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV99948744; called by muse, mutect2
- OR8H2 | c.744C>G p.V248= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- PADI6 | c.588C>A p.V196= | Silent (SNP) | VAF 11/225 reads (5%) | called by muse, mutect2
- PCDHA2 | c.1596G>A p.Q532= | Silent (SNP) | VAF 32/409 reads (8%) | called by muse, mutect2
- PITRM1 | c.235C>T p.L79= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- PLA2G4A | c.1875C>T p.P625= | Silent (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- RAB44 | c.2895C>A p.A965= | Silent (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2, varscan2
- RBFOX1 | c.231G>A p.P77= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs775977215, COSV60965127; called by mutect2, varscan2
- RBM20 | c.1221C>A p.P407= | Silent (SNP) | VAF 24/394 reads (6%) | catalogued as rs1243243290; called by muse, mutect2
- REM1 | c.228C>T p.S76= | Silent (SNP) | VAF 17/201 reads (8%) | called by muse, mutect2
- RIC8A | c.39T>A p.G13= | Silent (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
- ROS1 | c.495T>A p.I165= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- SLC18A2 | c.747G>T p.T249= | Silent (SNP) | VAF 17/294 reads (6%) | catalogued as COSV100042174; called by muse, mutect2
- SMOC2 | c.1173G>A p.K391= (on ENST00000356284 / NM_001166412.2; = p.K402= on NM_022138.3) | Silent (SNP) | VAF 17/288 reads (6%) | called by muse, mutect2
- STMND1 | c.495A>T p.T165= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- STXBP5L | c.2019G>T p.L673= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- TMEM67 | c.1599G>T p.G533= | Silent (SNP) | VAF 21/385 reads (5%) | called by muse, mutect2
- TMPRSS15 | c.240G>T p.V80= | Silent (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- TNR | c.1179C>A p.I393= | Silent (SNP) | VAF 17/208 reads (8%) | called by muse, mutect2
- TTLL10 | c.1158C>T p.C386= (on ENST00000379289 / NM_001130045.2; = p.C313= on NM_153254.3) | Silent (SNP) | VAF 14/229 reads (6%) | catalogued as rs1557482579; called by muse, mutect2
- USHBP1 | c.1867C>A p.R623= | Silent (SNP) | VAF 18/289 reads (6%) | catalogued as COSV99394026; called by muse, mutect2
- VAX2 | c.693G>C p.P231= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs781851281, COSV52265604; called by mutect2, varscan2
- ZFP36L2 | c.984G>A p.A328= | Silent (SNP) | VAF 5/52 reads (10%) | called by mutect2, varscan2
- ARMCX4 | c.1038+513G>T | Intron (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- CELA2A | c.-21C>A | 5'UTR (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- CLEC1B | c.-9C>G | 5'UTR (SNP) | VAF 13/97 reads (13%) | catalogued as COSV100046005; called by muse, mutect2, varscan2
- CLUHP11 | n.743A>T | RNA (SNP) | VAF 19/213 reads (9%) | called by muse, mutect2
- DPY19L2 | c.1580+2967G>T | Intron (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- ERBB4 | c.1946+20C>A | Intron (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- FADS2 | chr11:61826319 G>T | 5'Flank (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- FER1L4 | n.3095G>T | RNA (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- FOLH1 | c.119-664T>C | Intron (SNP) | VAF 15/236 reads (6%) | called by muse, mutect2
- G6PD | c.1457+12G>T | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- GAGE1 | c.*67C>T | 3'UTR (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- H2BP2 | n.1062-430G>T | Intron (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- PABPC1P2 | n.734A>G | RNA (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- POPDC3 | c.-251-4524C>A | Intron (SNP) | VAF 6/62 reads (10%) | catalogued as rs1324778421; called by muse, mutect2
- STX4 | chr16:31033059 G>A | 5'Flank (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- SYT7 | c.215+5170G>T | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- THRB | c.284-12804A>C | Intron (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- TTC19 | c.*662T>C | 3'UTR (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- UACA | c.*12G>T | 3'UTR (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2
- ZNF658B | n.2518T>C | RNA (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
